Somatic mutation profile of tumor specimen TCGA-HC-8260-01A (aliquot TCGA-HC-8260-01A-11D-2260-08) from TCGA case TCGA-HC-8260, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 43.5 years (15,884 days).
Specimen TCGA-HC-8260-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a8f83c8-2bdb-4385-b27c-adf0d3dc3de6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8260-10A (Blood Derived Normal), aliquot TCGA-HC-8260-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff4eb669-1838-450f-aed4-55920e73b5f1

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8080G>A p.G2694R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555127157, COSV53731189, COSV53752832; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ENOSF1 | c.347C>T p.A116V (on ENST00000340116 / NM_001354066.2; = p.A68V on NM_017512.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/93 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV51890942; called by muse, mutect2
- MAT1A | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as rs1456459077, COSV64744890; called by muse, mutect2
- PCDHA13 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV56480864; called by muse, mutect2, varscan2
- PLCG2 | c.2707A>G p.I903V | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs962919070, COSV63867869; called by muse, mutect2
- TET1 | c.493G>C p.V165L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV65382741; called by muse, mutect2
- TSR1 | c.1274A>G p.E425G | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV52156364; called by muse, mutect2, varscan2
- ZCCHC14 | c.2018G>T p.R673L (on ENST00000268616; = p.R810L on NM_015144.3) | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV51884587, COSV99233886, COSV99234277; called by muse, mutect2, varscan2
- FAM171A1 | c.2571C>T p.H857= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as rs1243447162, COSV65314179; called by muse, mutect2
- GCG | c.54C>T p.S18= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV64960951; called by muse, mutect2, varscan2
